Surgical pathology report (de-identified scan), TCGA case TCGA-06-0750, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0750-01A (Primary Tumor).

[page 1 of 2]
TCGA-D6-0750

Surgical Pathology Report

=====

had a right parietooccipital glioblastoma diagnosed a few weeks ago, currently for resection of residual tumor.

OPERATIVE DIAGNOSES
Craniotomy for brain tumor.

Operation/Specimen: A: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:
Brain, site not specified, excision: Glioblastoma.
See Comment.

COMMENT
The specimen contains portions of an astrocytic neoplastic proliferation that effaces the brain tissue, and has nuclear anaplasia, mitotic figures, microvascular cellular proliferation, and zones of necrosis, many with pseudopalisading, i.e. a glioblastoma (WHO IV/IV).

=====

PROCEDURES/ADDENDA

Immunohistology

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

Brain, tumor, MIB-1 Proliferation Index: 16%.
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by neoplastic cells. A very small minority of cells over expresses the p53 protein. The CD163 depicts a prominent population of positive cells intermingled with neoplastic cells. With the MIB-1 there is a proliferation index of about 16% in the more active areas.

Comment: The immuno results are consistent with a high histological grade glioma. The diagnosis remains as on the initial report.

[page 2 of 2]
GROSS DESCRIPTION

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: Received is a 2 x 1 x 0.6 cm. aggregate of irregular, red-tan to gray-white soft hemorrhagic glistening tissue fragments.

SECTIONS: A1, A2 entirely submitted.

ICD-9(s):

348.9 348.9

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:
Stain/cnt	Block Ordered Comment
CD163 Vector x 1	1
mGFAP-DA x 1	1
H/E x 1	1
MIB1-DA x 1	1
P53DO7 x 1	1
H/E x 1	2

*** End of Report ***

Source: NCI Genomic Data Commons file a49b7a2a-1022-4cc9-9673-72b3523b5130 (TCGA-06-0750.723B1F21-67A7-4A47-AC10-D297EA428C8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).